Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TF, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TF-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Requested By:

SLIDE DISPOSITION:

DIAGNOSIS:

G. Lung, right upper lobe, lobectomy: Invasive grade 4 (of 4) non-small cell carcinoma most consistent with adenocarcinoma, forming a well-circumscribed, solid 6.2 x 6.0 x 5.7 cm mass. Visceral pleural invasion is present. The portion of parietal pleura is not involved. Angiolymphatic invasion is absent. The bronchial margin is negative for tumor (by 3.2 cm). Multiple (8) intrapulmonary peribronchial lymph nodes are negative for tumor.

A. Lymph nodes, station 4R set #1, biopsy: Multiple (4) fragments of lymph nodes are negative for tumor.

B. Lymph nodes, station 4R set #2, biopsy: Multiple (7) fragments of lymph nodes are negative for tumor.

C. Lymph nodes, station 4L, biopsy: A single (1) lymph node is negative for tumor.

D. Lymph nodes, station 2R, biopsy: Multiple (14) fragments of lymph nodes are negative for tumor.

E. Lymph nodes, station 7 set #1, biopsy: Multiple (8) fragments of lymph nodes are negative for tumor.

F. Lymph nodes, station 9R, biopsy: A single (1) lymph node is negative for tumor.

H. Lymph nodes, station 7 set #2, biopsy: Multiple (7) fragments of lymph nodes are negative for tumor.

[With available surgical material, AJCCpT2bN0 7th edition,

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "station 4 right lymph node" is a 1.1 x 0.9 x 0.4 cm aggregate of lymphatic tissue which is all submitted. Grossed by

B. Received fresh labeled "station 4 right lymph node (set 2)" is a 0.2 x 0.2 x 0.1 cm aggregate of lymphatic tissue which is all submitted. Grossed by

C. Received fresh labeled "station 4 left lymph node" is a 0.6 x 0.4 x 0.3 cm aggregate of lymphatic tissue which is all submitted. Grossed by

D. Received fresh labeled "station 2 right lymph node" is a 0.3 x 0.3 x 0.2 cm aggregate of lymphatic tissue which is all submitted.

ICD-O-3
adenocarcinoma, NOS 8140/3
Site: lung upper lobe C34.1

JW
10/29/12

[page 2 of 2]
Grossed by

E. Received fresh labeled "station 7 lymph node" is a 0.3 x 0.2 x 0.1 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

F. Received fresh labeled "station 9 right lymph node" is a 0.4 x 0.3 x 0.2 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

G. Received fresh labeled "right upper lobe lung" is a 265.0 gram lobectomy with a 2.2 x 1.7 x 0.4 cm portion of adhered parietal pleura. There is a 6.2 x 6.0 x 5.7 cm well-circumscribed, solid, necrotic mass located peripherally, 3.2 cm from the shaved bronchial margin. The mass extends to the parietal pleura and umbilicates the visceral pleura which is inked and submitted perpendicularly. Multiple intrapulmonary peribronchial lymph nodes are identified. Representative sections are submitted. Grossed by

H. Received fresh labeled "station 7 lymph nodes" is a 0.3 x 0.3 x 0.2 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

BLOCK SUMMARY:

Part A: Station 4 right lymph node
1 Rt lower paratracheal LN

Part B: Station 4 right lymph node set 2
1 Rt lower paratracheal set 2

Part C: Station 4 left lymph node
1 Lt lower paratracheal LN

Part D: Station 2 right lymph node
1 Rt upper paratracheal LN(D1)

Part E: Station 7 lymph node
1 Subcarinal LN (E1)

Part F: Station 9 right lymph node
1 Pulmonary ligament LN

Part G: Right upper lobe lung
1 Rt bronchial margin
2 Peribronchial LN 1(G1)
3 Peribronchial LN 3(G2)
4 Peribronchial LN1of3(G3)
5 Peribronchial LN2of3(G3)
6 Peribronchial LN3of3(G3)
7 Rt upper lobe mass 1
8 Rt upper lobe mass 1
9 Rt upper lobe mass 2
10 Rt upper lobe mass 3
11 Peribronchial LN 2 (G4)
12 Peribronchial LN 2 (G5)
13 Rt upper lobe mass 4
~~14 Rt upper lobe mass 5~~
15 Rt upper lobe mass 6
16 Rt upper lobe mass 7
17 Rt upper lobe mass 8
18 Normal Rt lung

Part H: station 7 lymph nodes
1 Subcarinal LN 1(H1)
2 Subcarinal LN 4(H2)
3 Subcarinal LN 1(H3)
4 Subcarinal LN 1(H4)

Source: NCI Genomic Data Commons file 3850cd0c-83ba-4ccb-b4ea-eb0fa3de143d (TCGA-MP-A4TF.04511D30-B6E2-46F1-93B9-033B78257F1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).